Somatic mutation profile of tumor specimen TCGA-2H-A9GH-01A (aliquot TCGA-2H-A9GH-01A-11D-A37C-09) from TCGA case TCGA-2H-A9GH, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower third of esophagus; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 44.3 years (16,197 days).
Specimen TCGA-2H-A9GH-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 063f4d77-4fca-4e2b-a9e8-ad68d331fa50.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-2H-A9GH-11A (Solid Tissue Normal), aliquot TCGA-2H-A9GH-11A-11D-A37F-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3ca89b7e-1786-491a-a753-875ffc07e626

The open-access MAF lists 128 somatic variants for this specimen: 97 protein-altering or splice-affecting, 26 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 84, Silent 26, Nonsense Mutation 6, RNA 3, Frame Shift Del 3, In Frame Del 2, Intron 1, 3'UTR 1, Splice Site 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BTBD11 | c.3008A>C p.K1003T (on ENST00000280758 / NM_001018072.2; = p.K540T on NM_001017523.2) | Missense Mutation (SNP) | VAF 26/38 reads (68%) | hotspot (GDC flag); SIFT tolerated (0.44); PolyPhen probably damaging (0.946); catalogued as COSV55025836, COSV55028973, COSV55038748; called by muse, mutect2, varscan2
- ERBB2 | c.2329G>T p.V777L | Missense Mutation (SNP) | VAF 32/42 reads (76%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen benign (0.036); catalogued as rs121913471, COSV54062385, COSV54062767, COSV54069186; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.637C>T p.R213* | Nonsense Mutation (SNP) | VAF 28/37 reads (76%) | hotspot (GDC flag); catalogued as rs397516436, CM951226, COSV52665560, COSV52740638, COSV52746781, COSV52782151; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ACTL9 | c.310G>A p.V104M | Missense Mutation (SNP) | VAF 21/28 reads (75%) | SIFT tolerated (0.17); PolyPhen benign (0.01); catalogued as rs1568431475, COSV61005756; called by muse, mutect2, varscan2
- ADCY10 | c.2764G>A p.E922K | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.4); PolyPhen benign (0.005); catalogued as rs772519958; called by muse, mutect2, varscan2
- ADH1B | c.982G>A p.G328S | Missense Mutation (SNP) | VAF 15/27 reads (56%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs775525528; called by muse, mutect2, varscan2
- AK4 | c.451G>A p.V151I | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as rs765366640, COSV59196519, COSV59198835; called by muse, mutect2, varscan2
- ALAS2 | c.1307G>A p.R436Q | Missense Mutation (SNP) | VAF 22/32 reads (69%) | SIFT tolerated (0.29); PolyPhen benign (0.053); catalogued as rs780294973, COSV58193023; called by muse, mutect2, varscan2
- ATP8B4 | c.3362G>T p.R1121L | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.023); catalogued as rs764517232; called by muse, mutect2, varscan2
- BAG6 | c.338C>T p.S113F | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.856); catalogued as COSV52987638; called by muse, mutect2, varscan2
- BPIFB4 | c.355C>T p.R119* | Nonsense Mutation (SNP) | VAF 11/43 reads (26%) | catalogued as rs1004811130; called by muse, mutect2, varscan2
- CNTNAP5 | c.1627C>A p.L543M | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (0.67); PolyPhen probably damaging (0.982); catalogued as COSV101443485, COSV70489377; called by muse, mutect2, varscan2
- COL4A4 | c.4679G>A p.R1560H | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.591); catalogued as rs747362746, COSV61630559; called by muse, mutect2, varscan2
- COL6A1 | c.466G>T p.V156L | Missense Mutation (SNP) | VAF 21/83 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as rs778931297; called by muse, mutect2, varscan2
- CSPG5 | c.530T>A p.L177Q | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs979724401; called by muse, mutect2, varscan2
- EBF2 | c.1468T>G p.L490V | Missense Mutation (SNP) | VAF 20/36 reads (56%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.816); catalogued as rs1156879434, COSV68778596, COSV68780628; called by muse, mutect2, varscan2
- EPHA3 | c.1568A>G p.K523R | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT tolerated (0.39); PolyPhen benign (0.081); catalogued as COSV60719793, COSV60731934; called by muse, mutect2
- FCRL5 | c.674G>A p.R225Q | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs138632023, COSV62521471; called by muse, mutect2, varscan2
- FLG | c.6562A>G p.S2188G | Missense Mutation (SNP) | VAF 30/106 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV64236556, COSV64241700, COSV64244453; called by muse, mutect2, varscan2
- GMPR2 | c.77C>T p.S26F (on ENST00000355299 / NM_001351022.2; = p.S44F on NM_016576.5) | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV99164683; called by muse, mutect2, varscan2
- GRIA4 | c.146T>G p.F49C | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.886); catalogued as COSV56884195; called by muse, mutect2, varscan2
- GSN | c.2092G>C p.V698L | Missense Mutation (SNP) | VAF 14/24 reads (58%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV57999256; called by muse, mutect2, varscan2
- HEATR4 | c.1831G>A p.D611N | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT tolerated (0.39); PolyPhen benign (0.007); catalogued as rs1229905745; called by muse, mutect2, varscan2
- KIAA1755 | c.1401del p.T468Lfs*9 | Frame Shift Del (DEL) | VAF 24/75 reads (32%) | catalogued as rs752354849; called by mutect2, pindel, varscan2
- KIF20B | c.5098A>G p.I1700V (on ENST00000371728 / NM_001284259.2; = p.I1660V on NM_016195.4) | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs1396472277; called by muse, mutect2, varscan2
- LGI1 | c.625C>T p.R209C | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.676); catalogued as rs751825973; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LRCH4 | c.1684G>A p.E562K | Missense Mutation (SNP) | VAF 21/99 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.43); catalogued as rs764501444; called by muse, mutect2, varscan2
- LSS | c.1011G>C p.P337= | Splice Region (SNP) | VAF 25/47 reads (53%) | catalogued as rs759946114, COSV100711060, COSV100711091; called by muse, mutect2, varscan2
- MFAP5 | c.455G>A p.R152H | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); catalogued as rs761990899, COSV63945987; called by muse, mutect2, varscan2
- MTCL1 | c.2395C>G p.P799A (on ENST00000306329 / NM_001378206.1; = p.P439A on NM_015210.4) | Missense Mutation (SNP) | VAF 28/96 reads (29%) | SIFT tolerated (0.6); PolyPhen benign (0.061); catalogued as COSV100095135; called by muse, mutect2, varscan2
- MUC16 | c.8107A>C p.S2703R | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.883); catalogued as COSV101198092; called by muse, mutect2, varscan2
- OR52A5 | c.259T>G p.F87V | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV56616423; called by muse, mutect2, varscan2
- OR5AR1 | c.781A>G p.R261G | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as COSV57253653; called by muse, mutect2, varscan2
- OR5R1 | c.130G>T p.G44W | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100393442; called by muse, mutect2
- PI15 | c.590G>T p.W197L | Missense Mutation (SNP) | VAF 25/50 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV52642251; called by muse, mutect2, varscan2
- PIGT | c.370G>T p.D124Y | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.816); catalogued as rs966293005; called by muse, mutect2, varscan2
- PRKCQ | c.1325C>T p.T442M | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1274566995, COSV54106426; called by muse, mutect2, varscan2
- PTGER4 | c.981G>A p.W327* | Nonsense Mutation (SNP) | VAF 14/52 reads (27%) | catalogued as COSV56722037; called by muse, mutect2, varscan2
- SERPING1 | c.1466C>A p.P489H | Missense Mutation (SNP) | VAF 19/35 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as CD1212168, CM950183; called by muse, mutect2, varscan2
- STAG3 | c.2762G>A p.R921Q | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.139); catalogued as rs747309208; called by muse, mutect2, varscan2
- STON1 | c.1798C>T p.R600* | Nonsense Mutation (SNP) | VAF 21/41 reads (51%) | catalogued as rs776502062, COSV59127673; called by muse, mutect2, varscan2
- TAGLN3 | c.338C>T p.T113M | Missense Mutation (SNP) | VAF 21/90 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs779361155; called by muse, mutect2, varscan2
- TMEM132D | c.1757A>G p.E586G | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV101242896, COSV67162173; called by muse, mutect2, varscan2
- UNC13C | c.3985T>G p.L1329V | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.985); catalogued as COSV52842755, COSV52856856; called by muse, mutect2
- VEGFC | c.1066G>A p.G356R | Missense Mutation (SNP) | VAF 49/70 reads (70%) | SIFT tolerated (0.23); PolyPhen benign (0.1); catalogued as rs765702995, COSV99709821; called by muse, mutect2, varscan2
- ZNF436 | c.818C>T p.T273M | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs769807580, COSV58358706; called by muse, mutect2, varscan2
- ANGPT1 | c.250C>T p.Q84* | Nonsense Mutation (SNP) | VAF 5/28 reads (18%) | called by muse, mutect2
- ANK3 | c.6689A>G p.H2230R | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0); called by muse, mutect2, varscan2
- ATP13A4 | c.2531G>T p.G844V | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- CAMTA2 | c.3317T>C p.I1106T | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- CARD6 | c.1571A>G p.Q524R | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.795); called by muse, mutect2, varscan2
- CCDC102B | c.1344C>G p.N448K | Missense Mutation (SNP) | VAF 15/25 reads (60%) | SIFT deleterious (0.04); PolyPhen benign (0.148); called by muse, mutect2, varscan2
- CSMD3 | c.7078G>C p.E2360Q (on ENST00000297405 / NM_001363185.1; = p.E2256Q on NM_052900.3) | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.884); called by muse, mutect2, varscan2
- CYLC1 | c.780T>G p.N260K | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT tolerated (0.42); PolyPhen benign (0); called by muse, mutect2
- DCAF12L2 | c.1103G>T p.G368V | Missense Mutation (SNP) | VAF 21/24 reads (88%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.902); called by muse, mutect2, varscan2
- DMXL1 | c.6108_6110del p.L2037del | In Frame Del (DEL) | VAF 9/53 reads (17%) | called by mutect2, pindel, varscan2
- DYNC1H1 | c.3362A>G p.D1121G | Missense Mutation (SNP) | VAF 4/51 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- ELAPOR2 | c.1531G>A p.G511R (on ENST00000450689 / NM_001142749.3; = p.G344R on NM_152748.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ELOA2 | c.473C>G p.P158R | Missense Mutation (SNP) | VAF 17/30 reads (57%) | SIFT tolerated (0.51); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ELOA3B | c.862T>C p.F288L | Missense Mutation (SNP) | VAF 21/142 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- FANCM | c.2167G>A p.E723K | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- FBN1 | c.6047A>G p.E2016G | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- FBRS | c.972_983del p.A326_A329del (on ENST00000287468; = p.A846_A849del on NM_001105079.3) | In Frame Del (DEL) | VAF 4/20 reads (20%) | called by mutect2, varscan2
- FLNB | c.3221G>T p.G1074V | Missense Mutation (SNP) | VAF 29/57 reads (51%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GABRA1 | c.308A>G p.K103R | Missense Mutation (SNP) | VAF 3/36 reads (8%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.998); called by muse, mutect2
- GSDME | c.17C>T p.T6I | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HSPB7 | c.225C>G p.I75M | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); called by muse, mutect2, varscan2
- HTR1F | c.60G>T p.M20I | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT tolerated (0.27); PolyPhen benign (0); called by muse, mutect2, varscan2
- IGHV3-16 | c.266T>C p.I89T | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- KCNQ2 | c.2126C>A p.P709H (on ENST00000359125 / NM_172107.4; = p.P681H on NM_004518.6) | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.203); called by muse, mutect2, varscan2
- MCC | c.1534G>T p.A512S | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- NPC2 | c.11del p.L4Rfs*31 | Frame Shift Del (DEL) | VAF 4/32 reads (13%) | called by mutect2, pindel
- NUP62 | c.326C>A p.A109E | Missense Mutation (SNP) | VAF 35/67 reads (52%) | SIFT tolerated (0.11); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- OCLN | c.367G>A p.G123S | Missense Mutation (SNP) | VAF 29/68 reads (43%) | SIFT tolerated (0.11); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OGFRL1 | c.1010A>C p.N337T | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- OR8H1 | c.184T>G p.F62V | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCDHA12 | c.2225C>G p.S742C | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.198); called by muse, mutect2, varscan2
- PDLIM1 | c.722A>G p.K241R | Missense Mutation (SNP) | VAF 28/63 reads (44%) | SIFT tolerated (0.26); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- PLXNB2 | c.1476_1479del p.E492Dfs*37 | Frame Shift Del (DEL) | VAF 5/18 reads (28%) | called by mutect2, varscan2
- SAMD9L | c.2919A>C p.K973N | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT tolerated (0.49); PolyPhen benign (0); called by muse, mutect2, varscan2
- SEMA5A | c.1966T>A p.W656R | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- SESTD1 | c.1228G>T p.G410* | Nonsense Mutation (SNP) | VAF 24/47 reads (51%) | called by muse, mutect2, varscan2
- SLC49A4 | c.922A>T p.T308S | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT tolerated (0.39); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- SPTBN4 | c.1303G>C p.D435H | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- SRCAP | c.4030C>G p.P1344A | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TGM5 | c.556-2A>C p.X186_splice (on ENST00000220420 / NM_201631.4; = p.X104_splice on NM_004245.4) | Splice Site (SNP) | VAF 4/34 reads (12%) | called by muse, mutect2
- THSD7A | c.2374T>C p.S792P | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.251); called by muse, mutect2
- TNIK | c.1219G>A p.E407K | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- TTC3 | c.3461C>A p.P1154H | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.121); called by muse, mutect2, varscan2
- TTLL9 | c.671A>G p.K224R | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- UFL1 | c.1638C>G p.N546K | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT tolerated (0.27); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- UGT1A4 | c.335G>C p.R112T | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT tolerated (0.44); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- USP24 | c.4886G>C p.S1629T | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.2); PolyPhen benign (0.037); called by muse, mutect2
- ZC3H7A | c.2123T>C p.I708T | Missense Mutation (SNP) | VAF 17/32 reads (53%) | SIFT deleterious (0); PolyPhen benign (0.179); called by muse, mutect2, varscan2
- ZDHHC5 | c.1059G>T p.K353N | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.566); called by muse, mutect2, varscan2
- ZMYM2 | c.2659A>T p.I887F | Missense Mutation (SNP) | VAF 50/75 reads (67%) | SIFT deleterious (0); PolyPhen benign (0.18); called by muse, mutect2, varscan2
- ZNF511-PRAP1 | c.938A>G p.H313R | Missense Mutation (SNP) | VAF 9/15 reads (60%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- ADRA2A | c.318G>A p.L106= | Silent (SNP) | VAF 27/45 reads (60%) | called by muse, mutect2, varscan2
- ANXA10 | c.465C>G p.L155= | Silent (SNP) | VAF 39/53 reads (74%) | catalogued as rs780641657; called by muse, mutect2, varscan2
- CFH | c.1272A>G p.K424= | Silent (SNP) | VAF 23/41 reads (56%) | called by muse, mutect2, varscan2
- CNST | c.999G>A p.L333= | Silent (SNP) | VAF 23/47 reads (49%) | catalogued as rs756607182; called by muse, mutect2, varscan2
- DAW1 | c.66T>C p.H22= | Silent (SNP) | VAF 9/54 reads (17%) | called by muse, mutect2, varscan2
- DDI1 | c.618G>T p.L206= | Silent (SNP) | VAF 9/29 reads (31%) | catalogued as COSV56378509; called by muse, mutect2, varscan2
- DFFA | c.21C>A p.A7= | Silent (SNP) | VAF 3/50 reads (6%) | called by muse, mutect2
- ERN1 | c.2247G>A p.E749= | Silent (SNP) | VAF 17/24 reads (71%) | catalogued as rs765646119, COSV70500478; called by muse, mutect2, varscan2
- MUC6 | c.2790C>T p.I930= | Silent (SNP) | VAF 14/42 reads (33%) | called by muse, mutect2, varscan2
- NELL2 | c.2121T>G p.T707= | Silent (SNP) | VAF 7/36 reads (19%) | called by muse, mutect2, varscan2
- OR10X1 | c.243A>C p.A81= | Silent (SNP) | VAF 24/59 reads (41%) | catalogued as COSV63767066; called by muse, mutect2, varscan2
- OR4K1 | c.222T>C p.S74= | Silent (SNP) | VAF 27/56 reads (48%) | catalogued as rs748092566; called by muse, mutect2, varscan2
- OSBPL11 | c.801C>T p.C267= | Silent (SNP) | VAF 15/57 reads (26%) | catalogued as COSV99954019; called by muse, mutect2, varscan2
- PCDHGB2 | c.1332C>T p.D444= | Silent (SNP) | VAF 9/40 reads (23%) | catalogued as rs1431516547, COSV53935326; called by muse, mutect2, varscan2
- PCSK7 | c.87C>T p.F29= | Silent (SNP) | VAF 15/42 reads (36%) | catalogued as rs756817038; called by muse, mutect2, varscan2
- PIEZO2 | c.8178A>G p.E2726= | Silent (SNP) | VAF 20/39 reads (51%) | called by muse, mutect2, varscan2
- PROSER1 | c.1920C>T p.G640= | Silent (SNP) | VAF 16/26 reads (62%) | catalogued as rs1419461551, COSV61486055; called by muse, varscan2
- TCF20 | c.4560G>A p.T1520= | Silent (SNP) | VAF 13/44 reads (30%) | catalogued as rs1343314742, COSV100167039; called by muse, mutect2, varscan2
- TDRD6 | c.501C>T p.H167= | Silent (SNP) | VAF 17/27 reads (63%) | catalogued as COSV60175474; called by muse, mutect2, varscan2
- TGM6 | c.1302C>T p.R434= | Silent (SNP) | VAF 10/36 reads (28%) | catalogued as rs749578418, COSV52477556; ClinVar: benign; called by muse, varscan2
- TRIM37 | c.2769G>T p.G923= | Silent (SNP) | VAF 28/37 reads (76%) | called by muse, mutect2, varscan2
- UNC79 | c.1573C>A p.R525= (on ENST00000393151 / NM_001346218.2; = p.R348= on NM_020818.5) | Silent (SNP) | VAF 18/31 reads (58%) | called by muse, mutect2, varscan2
- URB2 | c.1218G>A p.P406= | Silent (SNP) | VAF 9/33 reads (27%) | called by muse, mutect2, varscan2
- WDFY3 | c.4656T>G p.T1552= | Silent (SNP) | VAF 19/32 reads (59%) | called by muse, mutect2, varscan2
- WDR74 | c.60G>A p.L20= | Silent (SNP) | VAF 16/55 reads (29%) | catalogued as COSV53931737; called by muse, mutect2, varscan2
- ZBED1 | c.1950C>T p.N650= | Silent (SNP) | VAF 58/75 reads (77%) | catalogued as rs781584629; called by muse, mutect2, varscan2
- CLCA3P | n.795T>A | RNA (SNP) | VAF 17/38 reads (45%) | called by muse, mutect2, varscan2
- MIR300 | n.22C>T | RNA (SNP) | VAF 19/35 reads (54%) | called by muse, mutect2, varscan2
- OFCC1 | n.202A>G | RNA (SNP) | VAF 12/34 reads (35%) | catalogued as rs1402106796; called by muse, mutect2, varscan2
- RIMS2 | c.4064-21130A>T | Intron (SNP) | VAF 15/57 reads (26%) | called by muse, mutect2, varscan2
- SRSF5 | c.*2C>T | 3'UTR (SNP) | VAF 5/27 reads (19%) | called by muse, mutect2, varscan2
